Somatic mutation profile of tumor specimen 0DNJBA from CCDI case PBCBNA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Spindle cell rhabdomyosarcoma; Tissue or organ of origin: Liver; Age at diagnosis: 3.8 years (1,382 days).
Specimen 0DNJBA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 980a830b-6d11-464f-ae3e-6c4bdade151a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNJA4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32a36209-35ab-4495-a59c-42f6b0a9f72f

The open-access MAF lists 64 somatic variants for this specimen: 45 protein-altering or splice-affecting, 9 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 9, Intron 4, 3'UTR 4, Nonsense Mutation 3, 5'Flank 1, 5'UTR 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 185/461 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- ACVR2A | c.373+1G>A p.X125_splice | Splice Site (SNP) | VAF 73/379 reads (19%) | catalogued as rs367638423; called by muse, mutect2, varscan2
- CLOCK | c.1478C>G p.S493* | Nonsense Mutation (SNP) | VAF 79/453 reads (17%) | catalogued as COSV104401531; called by muse, mutect2, varscan2
- DSCAML1 | c.1712T>G p.M571R (on ENST00000321322; = p.M511R on NM_020693.4) | Missense Mutation (SNP) | VAF 85/234 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs982848337, COSV58397508; called by muse, mutect2, varscan2
- EPHA5 | c.1937G>T p.G646V | Missense Mutation (SNP) | VAF 126/334 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV56656646; called by muse, mutect2, varscan2
- KCNJ3 | c.720G>C p.E240D | Missense Mutation (SNP) | VAF 96/406 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54533753, COSV54534095; called by muse, mutect2, varscan2
- KRTAP21-2 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 180/518 reads (35%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.208); catalogued as rs780402011, COSV61684194; called by muse, mutect2
- NSUN7 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 100/246 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs763392798; called by muse, mutect2, varscan2
- ORAI1 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 158/549 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs782448303, COSV57491404; called by muse, mutect2, varscan2
- P2RX7 | c.231G>T p.E77D | Missense Mutation (SNP) | VAF 146/579 reads (25%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.615); catalogued as COSV99947781; called by muse, mutect2, varscan2
- PTPN13 | c.4757G>T p.C1586F (on ENST00000411767 / NM_080683.3; = p.C1567F on NM_006264.3) | Missense Mutation (SNP) | VAF 166/372 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1169101084; called by muse, mutect2, varscan2
- RAB11FIP5 | c.846C>A p.S282R | Missense Mutation (SNP) | VAF 167/640 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as rs747541996; called by muse, mutect2, varscan2
- SETDB1 | c.184G>T p.A62S | Missense Mutation (SNP) | VAF 96/265 reads (36%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); catalogued as rs1462344298; called by muse, mutect2, varscan2
- SHC2 | c.1140C>A p.C380* | Nonsense Mutation (SNP) | VAF 36/323 reads (11%) | catalogued as rs1295582634; called by muse, mutect2, varscan2
- SLC13A1 | c.10T>C p.F4L | Missense Mutation (SNP) | VAF 99/416 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52015122, COSV99520259; called by muse, mutect2, varscan2
- TMEM262 | c.22G>A p.A8T (on ENST00000530719 / NM_001282448.1; = p.A6T on NM_001242631.2) | Missense Mutation (SNP) | VAF 134/352 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.691); catalogued as rs568583876, COSV51871016; called by muse, mutect2, varscan2
- TUBGCP2 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 111/286 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs759835583; called by muse, varscan2
- ACSL6 | c.1051C>A p.L351I (on ENST00000379240; = p.L376I on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/340 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- AMER1 | c.1622A>C p.N541T | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3838T>C p.F1280L | Missense Mutation (SNP) | VAF 151/768 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BTN2A2 | c.194A>G p.D65G | Missense Mutation (SNP) | VAF 124/373 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.012); called by mutect2, varscan2
- CHST8 | c.1262C>A p.A421E | Missense Mutation (SNP) | VAF 97/398 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- CKM | c.718A>C p.M240L | Missense Mutation (SNP) | VAF 74/819 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.22); called by muse, mutect2
- CLEC2D | c.545G>A p.W182* | Nonsense Mutation (SNP) | VAF 28/258 reads (11%) | called by muse, mutect2, varscan2
- CTAGE1 | c.1670C>A p.A557D | Missense Mutation (SNP) | VAF 109/214 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, varscan2
- CTU1 | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- DNAH7 | c.6124T>C p.F2042L | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, varscan2
- DOCK11 | c.1591G>T p.A531S | Missense Mutation (SNP) | VAF 84/112 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EML4 | c.2480G>A p.S827N | Missense Mutation (SNP) | VAF 103/305 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERMP1 | c.2609C>T p.S870F | Missense Mutation (SNP) | VAF 86/301 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- FXR1 | c.532G>T p.V178L | Missense Mutation (SNP) | VAF 113/270 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- LRRC38 | c.675G>T p.R225S | Missense Mutation (SNP) | VAF 131/330 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- NF1 | c.7226_7227del p.T2409Sfs*12 (on ENST00000358273 / NM_001042492.3; = p.T2388Sfs*12 on NM_000267.3) | Frame Shift Del (DEL) | VAF 95/154 reads (62%) | called by mutect2, varscan2
- OR4M1 | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 144/344 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.005); called by mutect2, varscan2
- OR5H15 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 168/446 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PLA2G4D | c.1562G>T p.C521F | Missense Mutation (SNP) | VAF 139/333 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- PLEKHG5 | c.3043G>T p.A1015S (on ENST00000400915 / NM_001042663.3; = p.A978S on NM_020631.6) | Missense Mutation (SNP) | VAF 180/447 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PWWP3A | c.683T>C p.L228S (on ENST00000627377; = p.L227S on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 97/234 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- RABGAP1 | c.3044C>A p.A1015E | Missense Mutation (SNP) | VAF 156/414 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- RBM46 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 80/425 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SEMG2 | c.1140G>T p.E380D | Missense Mutation (SNP) | VAF 69/677 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC26A9 | c.154G>C p.V52L | Missense Mutation (SNP) | VAF 209/499 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC8A1 | c.633C>A p.S211R | Missense Mutation (SNP) | VAF 112/488 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THOC3 | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, varscan2
- TRIM33 | c.2390C>A p.T797K | Missense Mutation (SNP) | VAF 134/367 reads (37%) | SIFT tolerated (0.9); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ABCB7 | c.708G>C p.L236= (on ENST00000373394 / NM_001271696.3; = p.L237= on NM_004299.6) | Silent (SNP) | VAF 108/136 reads (79%) | called by muse, mutect2, varscan2
- ATP1A1 | c.2136G>A p.V712= | Silent (SNP) | VAF 97/272 reads (36%) | called by muse, mutect2, varscan2
- EDNRA | c.303G>T p.L101= | Silent (SNP) | VAF 183/419 reads (44%) | catalogued as rs10305868, COSV100163213; called by muse, mutect2, varscan2
- GBE1 | c.1830C>A p.G610= | Silent (SNP) | VAF 27/352 reads (8%) | called by muse, mutect2
- LY75 | c.486G>T p.G162= | Silent (SNP) | VAF 130/516 reads (25%) | called by muse, varscan2
- MROH2A | c.153G>A p.T51= | Silent (SNP) | VAF 131/419 reads (31%) | catalogued as rs1279324004; called by muse, varscan2
- POLR3A | c.2292C>A p.G764= | Silent (SNP) | VAF 123/309 reads (40%) | called by muse, varscan2
- SYT15 | c.867C>T p.N289= | Silent (SNP) | VAF 50/312 reads (16%) | catalogued as rs376542477; called by muse, mutect2
- TBX22 | c.1299T>C p.Y433= | Silent (SNP) | VAF 90/105 reads (86%) | catalogued as rs774342643; called by muse, mutect2, varscan2
- FCRL6 | chr1:159800586 G>T | 5'Flank (SNP) | VAF 73/389 reads (19%) | called by muse, mutect2, varscan2
- FHOD3 | c.1197-8754A>G | Intron (SNP) | VAF 47/152 reads (31%) | called by muse, mutect2, varscan2
- PNMA3 | c.*52G>T | 3'UTR (SNP) | VAF 43/211 reads (20%) | called by muse, mutect2, varscan2
- PRR11 | c.*66G>T | 3'UTR (SNP) | VAF 107/301 reads (36%) | called by muse, mutect2, varscan2
- PTMA | c.*68C>A | 3'UTR (SNP) | VAF 7/153 reads (5%) | called by muse, mutect2
- PTPRN | c.167-64G>T | Intron (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- QARS1 | c.1296-34C>A | Intron (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2, varscan2
- RGPD4 | c.-74T>C | 5'UTR (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- RNF103 | c.367-90T>C | Intron (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- TOR4A | c.*59C>T | 3'UTR (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
